Somatic mutation profile of tumor specimen TCGA-5S-A9Q8-01A (aliquot TCGA-5S-A9Q8-01A-11D-A403-09) from TCGA case TCGA-5S-A9Q8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 51.4 years (18,785 days).
Specimen TCGA-5S-A9Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a018c0c-9ca7-4246-9c5d-a3cb1d4e093f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5S-A9Q8-10A (Blood Derived Normal), aliquot TCGA-5S-A9Q8-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a97911d-810f-46f7-8469-ca71d26e7eff

The open-access MAF lists 57 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 32, Silent 9, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 2, In Frame Del 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 26/67 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 41/74 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM132264, COSV64288500, COSV64301396, COSV64302611; called by muse, mutect2, varscan2
- RYR2 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs190140598, CM023669, COSV63663215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TAF1 | c.3613C>T p.R1205W (on ENST00000373790 / NM_138923.4; = p.R1226W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs864321629, CM1513563, COSV99336607; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.937A>T p.M313L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as COSV100941779; called by muse, mutect2, varscan2
- ANKRD17 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431668635, COSV58218767; called by muse, mutect2, varscan2
- ARID1A | c.3223del p.E1075Nfs*18 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as COSV100251177, COSV61372213; called by mutect2, pindel, varscan2
- AVPR2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as rs138974323, COSV61685966; called by muse, mutect2, varscan2
- CABP2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as rs754614044, COSV99590887; called by muse, mutect2, varscan2
- CCHCR1 | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs1476690538, COSV99459134; called by muse, mutect2, varscan2
- DSPP | c.3411C>A p.D1137E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.036); catalogued as rs201608130; called by muse, mutect2, varscan2
- DVL2 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs767205489, COSV99138737; called by muse, mutect2, varscan2
- ERBB4 | c.2659A>G p.M887V | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100726701; called by muse, mutect2, varscan2
- EXD2 | c.877C>T p.R293* (on ENST00000312994 / NM_001193362.1; = p.R168* on NM_018199.3) | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as rs770383229, COSV57279774; called by muse, mutect2, varscan2
- FAM117A | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99539600; called by muse, mutect2
- HUWE1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99473667; called by muse, mutect2, varscan2
- KRT85 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as COSV57736429; called by muse, mutect2, varscan2
- MAP4 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1373068868, COSV53140906; called by muse, mutect2, varscan2
- MAST3 | c.1312C>G p.R438G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99446047; called by muse, mutect2, varscan2
- MYO1A | c.2206-1G>A p.X736_splice | Splice Site (SNP) | VAF 39/75 reads (52%) | catalogued as COSV100271166, COSV100271227; called by muse, mutect2, varscan2
- NDOR1 | c.1201G>A p.V401M (on ENST00000371521 / NM_001144026.3; = p.V394M on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.515); catalogued as rs760157574, COSV61288872; called by muse, mutect2, varscan2
- OBSCN | c.21545G>A p.R7182H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs551576900, COSV100805069; called by muse, mutect2, varscan2
- PLCE1 | c.6190G>T p.E2064* | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | catalogued as COSV99596488; called by muse, mutect2, varscan2
- PLXNA1 | c.3183C>T p.S1061= | Splice Region (SNP) | VAF 27/62 reads (44%) | catalogued as rs752258540, COSV99303874; called by muse, mutect2, varscan2
- POLRMT | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs1245111840, COSV101646100; called by muse, mutect2, varscan2
- PRRG3 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs143153628, COSV100948680; called by muse, mutect2, varscan2
- PTEN | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.492); catalogued as CM981673, COSV100910801, COSV64288504; called by muse, varscan2
- PTPRM | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs917007136, COSV59848801; called by muse, mutect2, varscan2
- RBM19 | c.2426C>A p.S809* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV55687992; called by muse, mutect2, varscan2
- SI | c.1316C>A p.T439K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100016672; called by muse, mutect2, varscan2
- SLC46A1 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.319); catalogued as COSV100398133; called by muse, mutect2, varscan2
- SLC4A5 | c.3115G>A p.A1039T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); catalogued as COSV100697909; called by muse, mutect2, varscan2
- SRC | c.1497C>A p.C499* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100658172; called by muse, mutect2, varscan2
- TBCEL | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV52460072, COSV52462823; called by muse, mutect2, varscan2
- TRHDE | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV99671914; called by muse, mutect2, varscan2
- TTN | c.52883T>G p.F17628C (on ENST00000591111; = p.F10204C on NM_003319.4) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | PolyPhen probably damaging (0.912); catalogued as COSV100623971; called by muse, mutect2, varscan2
- VPS8 | c.2380C>G p.L794V (on ENST00000625842 / NM_001349294.1; = p.L792V on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs369647716, COSV99803354; called by muse, mutect2
- ZMYND15 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs773430156, COSV52639785, COSV99351632; called by muse, mutect2, varscan2
- ZNF536 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as rs777103163, COSV62826256; called by muse, mutect2, varscan2
- CCND1 | c.864_878del p.D289_V293del | In Frame Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- DYRK1A | c.821_830del p.L274Rfs*12 | Frame Shift Del (DEL) | VAF 40/80 reads (50%) | called by mutect2, pindel, varscan2
- EXOC6B | c.955_956del p.R319Afs*13 | Frame Shift Del (DEL) | VAF 30/85 reads (35%) | called by pindel, varscan2
- ICE1 | c.2217dup p.R740Sfs*14 | Frame Shift Ins (INS) | VAF 26/86 reads (30%) | called by mutect2, pindel, varscan2
- MAP7D2 | c.435_436del p.K146Vfs*15 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591dup p.M1531Nfs*4 | Frame Shift Ins (INS) | VAF 23/59 reads (39%) | called by mutect2, varscan2
- PTEN | c.709_723del p.K237_F241del | In Frame Del (DEL) | VAF 27/82 reads (33%) | called by pindel, varscan2
- CHRNA7 | c.1248C>T p.H416= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs780316084, COSV100181528; called by mutect2, varscan2
- DNER | c.804C>A p.V268= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100519767, COSV59160460; called by muse, mutect2, varscan2
- EPHA5 | c.516C>A p.I172= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99900465; called by muse, mutect2, varscan2
- PRAMEF18 | c.198G>T p.L66= | Silent (SNP) | VAF 51/413 reads (12%) | called by muse, mutect2
- PRAMEF19 | c.198G>T p.L66= | Silent (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- PXDNL | c.3039C>T p.T1013= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs772836199, COSV100685412; called by muse, mutect2, varscan2
- RCVRN | c.231C>T p.L77= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV56841584; called by muse, mutect2, varscan2
- TIGD3 | c.711G>A p.P237= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs1259077442, COSV99361843; called by muse, mutect2, varscan2
- ZXDB | c.1755A>G p.A585= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV100886010; called by muse, mutect2, varscan2
